Somatic mutation profile of tumor specimen 0DBHZB from CCDI case PBBLBN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.3 years (839 days).
Specimen 0DBHZB: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3138304-1b0b-4bac-a7eb-bd4831edda21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBFC8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3be3c47d-1c2c-4ab0-9b00-9068b43d0415

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Nonsense Mutation 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBI | c.2005C>T p.R669* | Nonsense Mutation (SNP) | VAF 98/245 reads (40%) | catalogued as rs201554996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCH1 | c.3472_3490del p.I1158Ffs*27 | Frame Shift Del (DEL) | VAF 180/246 reads (73%) | called by mutect2, varscan2
- IKZF3 | c.996G>A p.S332= | Silent (SNP) | VAF 185/457 reads (40%) | catalogued as rs760230065, COSV53101088; called by muse, mutect2, varscan2
